Somatic mutation profile of tumor specimen TCGA-3B-A9HL-01A (aliquot TCGA-3B-A9HL-01A-11D-A387-09) from TCGA case TCGA-3B-A9HL, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Specified parts of peritoneum; Age at diagnosis: 67.4 years (24,628 days).
Specimen TCGA-3B-A9HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52d8e8e3-df34-4772-8857-9dae72e071bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HL-10A (Blood Derived Normal), aliquot TCGA-3B-A9HL-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc55e9b-26aa-40aa-8ed1-5e1ad176e27a

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 33, Silent 9, Splice Site 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- UNC80 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs864321623, CM160381, COSV55897846; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.2749G>A p.E917K (on ENST00000547588 / NM_001122772.2; = p.E561K on NM_014770.4) | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as rs760901602, COSV99222162; called by muse, mutect2, varscan2
- ARMH4 | c.1242G>C p.L414F | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV99957555; called by muse, mutect2, varscan2
- ATP11B | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.227); catalogued as rs777534717, COSV100017474; called by muse, varscan2
- ATRX | c.4700G>A p.G1567D | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969985; called by muse, mutect2, varscan2
- CADM4 | c.665-1G>C p.X222_splice | Splice Site (SNP) | VAF 13/53 reads (25%) | catalogued as COSV99731297; called by muse, mutect2, varscan2
- CD58 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101043771; called by muse, mutect2, varscan2
- CELSR1 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99416682; called by muse, mutect2
- CFAP43 | c.2139G>A p.W713* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99530348; called by muse, mutect2, varscan2
- CILP | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.462); catalogued as COSV99972736; called by muse, mutect2, varscan2
- DYNC1LI2 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV99262823; called by muse, mutect2, varscan2
- EARS2 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV71942894; called by muse, mutect2, varscan2
- EMX2 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101463567; called by muse, mutect2, varscan2
- FBLN2 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs779267020, COSV99041546, COSV99851336; called by muse, mutect2, varscan2
- FHOD3 | c.2027G>T p.R676L (on ENST00000359247 / NM_001281739.3; = p.R693L on NM_025135.5) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.977); catalogued as COSV99939978; called by muse, mutect2, varscan2
- FKBP10 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV100387719; called by muse, mutect2, varscan2
- GTF2H1 | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV99786273; called by muse, mutect2, varscan2
- IFNG | c.311T>A p.F104Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99971073; called by muse, mutect2, varscan2
- INPP5F | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.046); catalogued as COSV100739974; called by muse, mutect2, varscan2
- LGR5 | c.786-1G>C p.X262_splice | Splice Site (SNP) | VAF 371/486 reads (76%) | catalogued as COSV99877426; called by muse, mutect2, varscan2
- MYH4 | c.619A>G p.K207E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99700286; called by muse, mutect2, varscan2
- MYO5C | c.4606C>T p.R1536C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs774783739, COSV99954041; called by muse, varscan2
- MYORG | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as rs899954736, COSV99898327; called by muse, mutect2, varscan2
- NEUROG1 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100130717, COSV59082804; called by muse, mutect2, varscan2
- NR2C1 | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100280158; called by muse, mutect2, varscan2
- OR10T2 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139047952, COSV57783558; called by muse, varscan2
- PHTF1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as rs376636226; called by muse, mutect2, varscan2
- POGZ | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.158); catalogued as COSV99652284; called by muse, mutect2, varscan2
- PTCH1 | c.1516C>G p.L506V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100107408; called by muse, mutect2, varscan2
- SEPTIN4 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV100421857; called by muse, mutect2
- SLC22A15 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768640311, COSV101047122; called by mutect2, varscan2
- TMPRSS3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.12); catalogued as rs369418733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC29 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100283136, COSV57271758; called by muse, mutect2, varscan2
- TTLL5 | c.3376G>A p.V1126M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs542956518, COSV100088940; called by muse, mutect2, varscan2
- TTN | c.76199C>T p.T25400M (on ENST00000591111; = p.T17976M on NM_003319.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | PolyPhen benign (0.251); catalogued as rs755178087, COSV59901973; called by muse, mutect2, varscan2
- UBTF | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV100255762; called by muse, mutect2, varscan2
- ADGRV1 | c.15057T>C p.D5019= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV101315441, COSV67985134; called by muse, mutect2, varscan2
- COL5A1 | c.5025C>T p.A1675= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs560774273, COSV65674980; called by muse, mutect2, varscan2
- DMXL1 | c.7845G>A p.K2615= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV100223178; called by muse, mutect2, varscan2
- FZD6 | c.450A>G p.T150= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100708286; called by muse, mutect2, varscan2
- HSD17B1 | c.258C>T p.D86= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs762229140, COSV56798283; called by muse, mutect2, varscan2
- KIR2DL1 | c.201C>T p.N67= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as rs144426670; called by muse, mutect2
- MYO16 | c.540G>A p.L180= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99193495; called by muse, mutect2, varscan2
- TMEM40 | c.582C>T p.F194= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs199796616, COSV53149352; called by muse, mutect2, varscan2
- VARS1 | c.2824C>A p.R942= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100791771, COSV100791776; called by muse, mutect2
